Somatic mutation profile of tumor specimen MMRF_1432_1_BM_CD138pos (aliquot MMRF_1432_1_BM_CD138pos_T1_KAS5U_L01707) from MMRF case MMRF_1432, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.8 years (24,764 days).
Specimen MMRF_1432_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d5c5641-20b9-42fa-a35d-ce04712e7987.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1432_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1432_1_PB_CD3pos_C2_KAS5U_L01715; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef43aae1-3917-4935-91f5-b2193b67bf01

The open-access MAF lists 54 somatic variants for this specimen: 21 protein-altering or splice-affecting, 8 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 16, 3'UTR 13, Silent 8, Intron 4, 3'Flank 4, Splice Site 3, 5'UTR 2, Splice Region 2, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANO4 | c.2492G>A p.R831Q (on ENST00000392977 / NM_001286615.2; = p.R796Q on NM_178826.4) | Missense Mutation (SNP) | VAF 55/112 reads (49%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as rs868314489, COSV54590940; called by muse, mutect2, varscan2
- CDH7 | c.2327A>G p.Y776C | Missense Mutation (SNP) | VAF 27/496 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1175436139; called by muse, mutect2
- IFNL1 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.11); PolyPhen benign (0.023); catalogued as rs1285881612; called by muse, mutect2, varscan2
- IGKV4-1 | c.283A>G p.T95A | Missense Mutation (SNP) | VAF 45/48 reads (94%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as rs578059335; called by muse, varscan2
- IGKV4-1 | c.359C>G p.T120S | Missense Mutation (SNP) | VAF 35/38 reads (92%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs749276071; called by muse, varscan2
- OSBPL5 | c.2050C>T p.R684W | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746630605, COSV55140887; called by mutect2, varscan2
- OTULIN | c.468+5G>A | Splice Region (SNP) | VAF 4/52 reads (8%) | catalogued as rs1466343593; called by muse, mutect2
- STON1 | c.1951C>A p.L651M | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV59134877; called by muse, mutect2, varscan2
- DNAH5 | c.12667T>G p.F4223V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- GOLGA2 | c.68G>T p.R23M | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2
- KHDC1L | c.296-2A>G p.X99_splice | Splice Site (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- MRPL38 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 53/109 reads (49%) | SIFT tolerated (0.54); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NEB | c.8478C>G p.I2826M | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- NEK10 | c.3220A>G p.N1074D | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.999); called by muse, mutect2
- PAPPA | c.1955T>A p.V652D | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PSMG1 | c.393+1G>A p.X131_splice | Splice Site (SNP) | VAF 41/85 reads (48%) | called by mutect2, varscan2
- REXO1 | c.3091-7C>T | Splice Region (SNP) | VAF 32/81 reads (40%) | called by muse, mutect2, varscan2
- ROBO3 | c.3554G>T p.S1185I | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.017); called by mutect2, varscan2
- RPL4 | c.834-1G>C p.X278_splice | Splice Site (SNP) | VAF 13/175 reads (7%) | called by muse, mutect2
- SALL4 | c.1797T>G p.C599W | Missense Mutation (SNP) | VAF 12/278 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF382 | c.1079C>T p.S360F | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by muse, mutect2
- ADRA1B | c.1269G>A p.S423= | Silent (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- ANKK1 | c.1746C>T p.Y582= | Silent (SNP) | VAF 37/76 reads (49%) | catalogued as rs373856752; called by muse, mutect2, varscan2
- BAG1 | c.90G>C p.P30= | Silent (SNP) | VAF 14/24 reads (58%) | called by muse, mutect2, varscan2
- CAMK2B | c.567G>A p.E189= | Silent (SNP) | VAF 58/110 reads (53%) | catalogued as rs1204336480; called by muse, mutect2, varscan2
- LRP2 | c.5799C>G p.L1933= | Silent (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- MMD2 | c.279G>A p.K93= | Silent (SNP) | VAF 36/74 reads (49%) | called by muse, mutect2
- RGS12 | c.3879G>A p.K1293= | Silent (SNP) | VAF 32/69 reads (46%) | catalogued as COSV58750534; called by muse, mutect2, varscan2
- TRAPPC2B | c.402G>T p.G134= | Silent (SNP) | VAF 19/172 reads (11%) | catalogued as COSV99987898; called by muse, mutect2, varscan2
- ABCB8 | c.95+52A>G | Intron (SNP) | VAF 10/20 reads (50%) | catalogued as rs774155720; called by muse, varscan2
- AC092818.1 | n.454T>A | RNA (SNP) | VAF 14/84 reads (17%) | called by mutect2, varscan2
- ANKEF1 | c.*417G>A | 3'UTR (SNP) | VAF 13/43 reads (30%) | catalogued as rs554557726; called by muse, mutect2, varscan2
- ATP8A2 | c.*159G>A | 3'UTR (SNP) | VAF 4/58 reads (7%) | catalogued as rs1032346596, COSV54981073; called by muse, mutect2
- EHD1 | c.*14C>T | 3'UTR (SNP) | VAF 6/105 reads (6%) | catalogued as rs1394972750, COSV57734936; called by muse, mutect2
- FAM131B | c.*2534G>A | 3'UTR (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- GPR88 | c.*1056G>A | 3'UTR (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- GRID2 | c.-380G>T | 5'UTR (SNP) | VAF 5/8 reads (63%) | called by muse, mutect2, varscan2
- IFRD1 | chr7:112476009 T>G | 3'Flank (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- IL1RAP | c.*1207A>T | 3'UTR (SNP) | VAF 55/105 reads (52%) | called by muse, mutect2, varscan2
- KIAA1755 | c.*626C>T | 3'UTR (SNP) | VAF 18/31 reads (58%) | called by mutect2, varscan2
- LRP4 | c.*1217C>T | 3'UTR (SNP) | VAF 54/124 reads (44%) | called by muse, mutect2, varscan2
- NDST2 | chr10:73801805 C>A | 3'Flank (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- NFIB | c.*4294T>A | 3'UTR (SNP) | VAF 5/79 reads (6%) | called by muse, mutect2
- NPRL3 | c.1352-89C>G | Intron (SNP) | VAF 4/18 reads (22%) | catalogued as rs1277566572; called by muse, mutect2
- PGAP1 | c.*648A>C | 3'UTR (SNP) | VAF 12/197 reads (6%) | called by muse, mutect2
- PTPN4 | c.*5672T>G | 3'UTR (SNP) | VAF 5/134 reads (4%) | called by muse, mutect2
- RBFOX1 | chr16:7712197 G>T | 3'Flank (SNP) | VAF 20/100 reads (20%) | catalogued as COSV60948443; called by muse, mutect2, varscan2
- RN7SL319P | chr15:75783004 G>T | 5'Flank (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- SHC4 | c.841-4967C>G | Intron (SNP) | VAF 38/676 reads (6%) | called by muse, mutect2
- SLC6A2 | chr16:55705276 G>A | 3'Flank (SNP) | VAF 107/111 reads (96%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.*3887G>T | 3'UTR (SNP) | VAF 13/255 reads (5%) | called by muse, mutect2
- STEAP1B | c.706-18839A>G | Intron (SNP) | VAF 8/186 reads (4%) | called by muse, mutect2
- TMEM165 | c.-197C>G | 5'UTR (SNP) | VAF 18/30 reads (60%) | catalogued as rs532235169; called by muse, mutect2, varscan2
- TRAM1L1 | c.*362T>G | 3'UTR (SNP) | VAF 40/100 reads (40%) | called by muse, varscan2
